Gene-level copy-number profile of tumor specimen TCGA-42-2588-01A from TCGA case TCGA-42-2588, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 61.3 years (22,377 days).
Specimen TCGA-42-2588-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.54c64bfb-98e2-4161-bb35-d03295584bd3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-42-2588-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1d7a9e27-7088-4041-af96-9eae3e8d646c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 6,697; copy number 2: 39,381; copy number 3: 8,376; copy number 4: 3,276; copy number 5: 1,034; copy number 6: 730; copy number 7: 254; copy number 8: 30; copy number 9: 16; copy number 13: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-42-2588-01A-01D-1043-01): tumor purity 0.57, ploidy 2.25, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:68,573,782–68,835,541, 10 genes (within-gene range 0–1): AC126773.3, AC126773.6, AC126773.1, AC126773.2, CDH3, AC126773.4, AC126773.5, HSPE1P5, CDH1, RNA5SP429.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,072 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,383,838–40,771,603, 82 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr1:56,823,679–56,918,223, 2 genes, copy number 5 (within-gene range 3–5): AL360295.1, C8A.
- chr1:147,482,238–148,288,951, 29 genes, copy number 6: OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1, AC239809.2, RNVU1-22, LINC01731, AC245100.3.
- chr1:148,295,180–148,344,638, 6 genes, copy number 6: LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21.
- chr1:151,279,678–151,853,712, 41 genes, copy number 5: ZNF687-AS1, ZNF687, PI4KB, RN7SL444P, AL391069.2, RFX5, AL391069.1, RFX5-AS1, SELENBP1, PSMB4, POGZ, RNY4P25, CGN, AL365436.3, TUFT1, AL365436.2, MIR554, AL365436.1, SNX27, AL391335.1, RNU6-1062P, CELF3, AL589765.1, RIIAD1, RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4, RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5.
- chr1:209,107,503–209,567,673, 11 genes, copy number 5 (within-gene range 3–5): AC092810.3, AC092810.2, AC092810.1, TFDP1P1, ATP5MC2P1, LINC01696, LINC01698, MIR205HG, MIR205, AL023754.1, AL023754.2.
- chr3:52,455,118–58,666,834, 124 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr3:78,038,705–78,161,992, 4 genes, copy number 5: LINC02077, AC117462.1, RN7SL647P, RN7SKP61.
- chr3:89,107,621–90,030,495, 5 genes, copy number 7 (within-gene range 4–7): EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3.
- chr3:151,733,916–151,928,175, 7 genes, copy number 5 (within-gene range 3–5): AADACL2, AADACL2-AS1, AC068647.1, AADACP1, AC068647.2, AADAC, SUCNR1.
- chr3:160,472,348–160,697,060, 7 genes, copy number 6: RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72.
- chr3:171,058,414–171,460,408, 1 gene, copy number 6 (within-gene range 3–6): TNIK.
- chr3:171,439,526–172,401,669, 13 genes, copy number 6 (within-gene range 4–6): Y_RNA, AC092919.1, AC092919.2, RNU6-348P, AC008134.1, PLD1, TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1, FNDC3B, RPS27AP8, RN7SL141P.
- chr3:179,236,691–179,465,328, 10 genes, copy number 5: KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1, GNB4, AC007620.2, AC007620.3, AC007620.1, MTHFD2P7.
- chr3:181,505,075–181,867,154, 10 genes, copy number 5: RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1.
- chr5:2,261,859–5,694,742, 40 genes, copy number 5–7: AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1, AC026736.1.
- chr5:26,473,505–27,121,150, 7 genes, copy number 5 (within-gene range 4–5): AC025475.2, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9.
- chr5:32,221,932–35,429,277, 54 genes, copy number 5: AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, AC008766.1, NPR3, AC025459.1, AC010343.3, LINC02120, AC034223.1, AC034223.2, AC010343.2, AC010343.1, LINC02160, AC025472.1, AC034231.1, TARS1, TOMM40P3, AC034232.1, ADAMTS12, RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1, AC138409.2, AC138409.1, AC138409.3, AC138853.1, AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2, PRLR, AC010368.1, U3.
- chr5:36,485,343–37,753,435, 23 genes, copy number 5 (within-gene range 4–5): RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P.
- chr5:171,724,575–172,283,764, 9 genes, copy number 6 (within-gene range 4–6): AC022440.1, AC011410.1, SMIM23, FBXW11, STK10, EFCAB9, UBTD2, AC024561.1, KLF3P1.
- chr6:6,346,465–6,622,771, 1 gene, copy number 6 (within-gene range 4–6): LY86-AS1.
- chr6:6,450,356–6,995,727, 13 genes, copy number 6: AL162719.1, CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1.
- chr6:9,596,110–13,287,843, 64 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:25,754,699–26,246,996, 47 genes, copy number 5: SLC17A4, SLC17A1, SLC17A3, H2AC3P, H2BP5, SLC17A2, TRIM38, U91328.2, U91328.1, U91328.3, H3P26, H1-1, H3C1, H4C1, H4C2, H3C2, H2AC4, H2BC3, H2AC5P, H3C3, H1-2, HFE, H4C3, H1-6, H2BC4, H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P, H3C6, H2AC9P, H1-3, H4C6, H4C7.
- chr6:30,184,455–31,815,283, 152 genes, copy number 5 (broad region; genes not listed).
- chr7:107,660,828–108,130,361, 10 genes, copy number 5 (within-gene range 4–5): SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4.
- chr8:52,110,839–55,542,054, 50 genes, copy number 5–6 (within-gene range 2–6): ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1, NPBWR1, AC009800.1, AC009646.1, AC009646.2, OPRK1, AC131902.1, AC022034.3, AC131902.2, AC022034.1, AC022034.4, AC022034.2, MAPK6P1, AC103778.1, ATP6V1H, RGS20, AC113194.1, RPS27AP13, RNU6-1331P, TCEA1, AC100821.1, AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1, AC044836.1, RNU105C, AC027250.1, AC027250.2, RN7SL250P, SOX17, AC091076.1, TRMT112P7, RP1, SEC11B, AC090151.1, AC084834.1, XKR4, AC022679.2, AC022679.1.
- chr8:71,779,605–145,066,685, 1,152 genes, copy number 5–13 (broad region; genes not listed).
- chr10:10,257,169–10,462,361, 6 genes, copy number 5: CUX2P1, AL354916.1, AL583859.1, CELF2-DT, AL583859.2, AL583859.3.
- chr10:74,744,386–76,560,168, 30 genes, copy number 5–6 (within-gene range 4–6): FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1.
- chr11:65,695,552–66,509,657, 61 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:84,448,625–84,449,878, 1 gene, copy number 5: AC087888.1.

Autosomal genes at a single copy (total copy number 1): 6,697. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
